Somatic mutation profile of tumor specimen ALCH-ADBK-TTP1-A (aliquot ALCH-ADBK-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADBK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,018 days).
Specimen ALCH-ADBK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae7e58e8-a80d-4283-a7d0-2bb301e6b3f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADBK-NB1-A (Blood Derived Normal), aliquot ALCH-ADBK-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30f4aa43-8970-4133-9e06-87d98f252afb

The open-access MAF lists 49 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 2, Intron 2, 3'UTR 1, 5'UTR 1, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2497T>G p.L833V | Missense Mutation (SNP) | VAF 622/1234 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs397517126, COSV51773059, COSV51776947; ClinVar: uncertain significance; called by muse, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 736/1502 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- BOC | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 123/1088 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV56348632; called by muse, mutect2, varscan2
- CDH20 | c.837C>A p.Y279* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as rs1287002117; called by muse, mutect2
- DSG2 | c.2139G>T p.E713D | Missense Mutation (SNP) | VAF 95/723 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV55197778; called by muse, mutect2, varscan2
- FBXW12 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1350657787; called by muse, mutect2, varscan2
- GPR176 | c.1277G>T p.S426I | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs1466071306; called by muse, mutect2
- GSG1 | c.899G>A p.R300Q (on ENST00000651961 / NM_001080555.4; = p.R264Q on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs545591892; called by muse, mutect2
- KDM6B | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 48/641 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs762712166; called by muse, mutect2
- KLHDC2 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs773766089; called by muse, mutect2, varscan2
- LOXL3 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs372708796, COSV51208628; called by muse, mutect2, varscan2
- PLXNA4 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs143690954, COSV58111460; called by muse, mutect2, varscan2
- RBM33 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 103/489 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs143396425, COSV56637154; called by muse, mutect2, varscan2
- TG | c.4772C>T p.S1591F | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368512066, COSV55086140; called by muse, mutect2, varscan2
- ADGRA3 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AJM1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 147/606 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- AP3M1 | c.815T>A p.I272K | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- APOB | c.8915A>G p.Q2972R | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATR | c.3490C>T p.P1164S | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.067); called by muse, mutect2
- ERCC4 | c.2066G>T p.R689L | Missense Mutation (SNP) | VAF 70/440 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMN1 | c.1994A>G p.H665R | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- HRH1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KEAP1 | c.723C>G p.C241W | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- MOXD1 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 156/675 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PARP3 | c.625A>T p.M209L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PLXNA3 | c.4220+1G>C p.X1407_splice | Splice Site (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- PPIP5K2 | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- SERPINA4 | c.927T>G p.N309K | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by mutect2, varscan2
- SNED1 | c.1910A>G p.Y637C | Missense Mutation (SNP) | VAF 92/496 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM214 | c.765T>A p.C255* | Nonsense Mutation (SNP) | VAF 121/798 reads (15%) | called by muse, mutect2, varscan2
- USP6 | c.3569A>G p.N1190S | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CCDC168 | c.13170C>T p.D4390= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs543696515, COSV59423675; called by muse, mutect2, varscan2
- CDH15 | c.2226C>T p.D742= | Silent (SNP) | VAF 41/620 reads (7%) | catalogued as rs370556933; called by muse, mutect2
- CUL2 | c.288G>A p.K96= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- FAM189A1 | c.1035C>T p.S345= | Silent (SNP) | VAF 50/326 reads (15%) | catalogued as rs779896532, COSV99721556; called by muse, mutect2, varscan2
- HSPA12A | c.1368C>T p.I456= | Silent (SNP) | VAF 123/565 reads (22%) | catalogued as rs781955087; called by muse, mutect2, varscan2
- KATNIP | c.480T>C p.D160= | Silent (SNP) | VAF 189/927 reads (20%) | called by muse, mutect2, varscan2
- LPA | c.4269C>A p.I1423= | Silent (SNP) | VAF 63/421 reads (15%) | catalogued as COSV60301800; called by muse, mutect2, varscan2
- PLPPR4 | c.1923T>A p.G641= | Silent (SNP) | VAF 109/445 reads (24%) | called by muse, mutect2, varscan2
- PRRX1 | c.588G>A p.A196= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs758418083, COSV53417696; called by muse, mutect2
- TMEM132E | c.204C>T p.V68= | Silent (SNP) | VAF 178/762 reads (23%) | catalogued as rs150026307; called by muse, varscan2
- TRPC4 | c.2295G>T p.A765= (on ENST00000379705 / NM_016179.4; = p.A770= on NM_003306.3) | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- UNC13A | c.654A>G p.Q218= | Silent (SNP) | VAF 235/770 reads (31%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826624 A>G | 3'Flank (SNP) | VAF 39/344 reads (11%) | called by muse, mutect2, varscan2
- CCDC144NL | n.582T>C | RNA (SNP) | VAF 66/570 reads (12%) | called by muse, mutect2, varscan2
- MTHFSD | c.124-140T>A | Intron (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- MTR | c.-63C>T | 5'UTR (SNP) | VAF 91/387 reads (24%) | catalogued as rs1347143214; called by muse, mutect2, varscan2
- PIEZO1 | c.6472-401C>T | Intron (SNP) | VAF 27/340 reads (8%) | catalogued as rs769944561; called by muse, mutect2
- SEMA6C | c.*182C>T | 3'UTR (SNP) | VAF 59/294 reads (20%) | called by muse, mutect2, varscan2
